Surgical pathology report (de-identified scan), TCGA case TCGA-FG-8189, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-8189-01B (Primary Tumor).

SURGICAL PATHOLOGY REPORT

Race: CAUCASIAN
DOB/Sex: F

FINAL DIAGNOSIS

A-C. RIGHT TEMPORAL LOBE OF BRAIN, TUMOR, BIOPSIES AND REMOVAL:
-- OLIGODENDROGLIOMA (WHO GRADE II).

Note: An addendum will be issued pending analyses for deletions of chromosomes 1p and 19q.

Electronically Signed Out By

By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consultation:

A and B: Microscopic: Glioma, favor grade 2 oligodendroma.

Clinical History:

Right frontal temporal brain mass

Specimens Submitted As:

A:(R) TEMPORAL MASS
B:DEEP TEMPORAL NEOPLASM
C:RIGHT TEMPORAL TUMOR

ICD-0-3

Oligodendroglioma, NOS 9450/3
Site: brain, temporal lobe C71.2

hw

10/4/12

Gross Description:

A. Received fresh, for intraoperative consult, post fixed in formalin, labeled with the patient's name and hospital number, and "right temporal mass", are multiple fragments of tan-pink, irregular, soft tissue measuring 0.7 x 0.5 x 0.3-cm. Part of the specimen was submitted for touch imprint and frozen section analysis. The remainder of the frozen section and the rest of the specimen are submitted entirely in 2 cassettes.

B. Received fresh, for intraoperative consult, post fixed in formalin, labeled with the patient's name and hospital number, and "deep temporal neoplasm", are multiple fragments of tan-pink, irregular, soft tissue measuring 0.8 x 0.6 x 0.2-cm. The specimen is entirely submitted for frozen section analysis. The remainder of the frozen section is submitted entirely in 1 cassette.

C: Received fresh, labeled with the patient's name and number, is an irregular pale tan to pink-tan soft cribriform tissue fragment measuring 5.9 x 4.6 x 2.3 cm. A portion is given to [REDACTED]. Submitted entirely in 18 cassettes.

Summary of cassettes:

Specimen	Label	Site
A	1	frozen section remnant
	2	rest of specimen

CACF + REMOTE

hw 10/4/12

Source: NCI Genomic Data Commons file 03645c1c-4a46-477f-9aba-9ccc243b4bd5 (TCGA-FG-8189.0645C7FA-38CE-48A5-B873-FEB4D4CF5952.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).